Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4884, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4884-01A (Primary Tumor).

Surgery Date:

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA, CLEAR CELL (CONVENTIONAL) TYPE, FUHRMAN
NUCLEAR GRADE 3 (4.5 CM IN
MAXIMUM DIMENSION).

VASCULAR INVASION PRESENT. (SEE COMMENT)

Renal vein and ureteral margins, no tumor present.

(B) PERINEPHRIC FAT:

Adipose tissue, no tumor present.

COMMENT

Vascular invasion is present in a large caliber vessel in the renal
sinus.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A nephrectomy specimen (15.0 x 11.0 x 9.0 cm)
including kidney (9.0 x 5.5 x 3.0 cm), ureter and attached perinephric
fat..

There is a centrally located 4.5 x 4.0 x 3.7 cm grossly encapsulated
yellow-tan mass pushing into the renal sinus. There is no extension
through the renal capsule. It is grossly 4.5 cm from the Gerota's
fascia. There is no gross renal vein involvement.

The surrounding renal parenchyma is grossly unremarkable with a single
simple cyst (0.5 x 0.5 x 0.5 cm). Portions are submitted for tumor
bank.

INK CODE: Black: Gerota's fascia.

SECTION CODE: A1, ureter/vascular margin; A2-A5, tumor in relation
to renal sinus; A6-A8, tumor in relation to renal parenchyma and renal
capsule; A9-A11, myxoid fleshy area of renal tumor; A12,A13, overlying
Gerota's fascia; A14, non-tumor of kidney including simple cyst.

(B) PERINEPHRIC FAT - The specimen consists of an unoriented fragment
of adipose tissue measuring 6.0 x 4.0 x 2.0 cm. The specimen is
serially sectioned. No lesions or lymph nodes are grossly identified.
Representative sections are submitted in cassettes B1 and B2.

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, M-82123

Source: NCI Genomic Data Commons file 18be5483-7a9e-49e4-b842-f017803c9976 (TCGA-CJ-4884.86A67CBA-4A99-4982-AC12-474C42986497.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).